Somatic mutation profile of tumor specimen TCGA-ER-A19F-06A (aliquot TCGA-ER-A19F-06A-11D-A196-08) from TCGA case TCGA-ER-A19F, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.9 years (30,640 days).
Specimen TCGA-ER-A19F-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 134638b3-f509-42db-8dab-48e1a9403653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19F-10A (Blood Derived Normal), aliquot TCGA-ER-A19F-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bfcb35a-16cc-42f7-ba4f-4d77e0747209

The open-access MAF lists 1,148 somatic variants for this specimen: 753 protein-altering or splice-affecting, 362 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 682, Silent 362, Nonsense Mutation 43, Intron 14, Splice Site 12, RNA 9, Splice Region 9, 3'UTR 5, Frame Shift Del 4, 3'Flank 3, 5'Flank 2, In Frame Del 1.

Variants (750 of 1,148; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs1555321351, COSV57397905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4588C>T p.R1530* | Nonsense Mutation (SNP) | VAF 36/79 reads (46%) | catalogued as rs397516225, COSV62516192; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SLC12A6 | c.2023C>T p.R675* (on ENST00000354181 / NM_001365088.1; = p.R624* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 58/153 reads (38%) | catalogued as rs121908428, CM022672, COSV99273634; ClinVar: pathogenic; called by mutect2, varscan2
- ABAT | c.1118A>T p.N373I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV51625070; called by muse, mutect2, varscan2
- ABCA6 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV52636600; called by muse, mutect2, varscan2
- ABRA | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61732857; called by muse, mutect2, varscan2
- ACADL | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV52054189; called by muse, mutect2, varscan2
- ACADM | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1389882916, COSV63720685; called by mutect2, varscan2
- ACAN | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as rs753349925, COSV61363736; called by muse, mutect2, varscan2
- ACAN | c.5471G>A p.G1824D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781252881, COSV61363748; called by muse, mutect2, varscan2
- ACSM1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54637531; called by muse, mutect2, varscan2
- ACTN3 | c.804G>A p.Q268= | Splice Region (SNP) | VAF 24/61 reads (39%) | catalogued as COSV101557917; called by muse, varscan2
- ADAM11 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV52347579; called by muse, mutect2
- ADAM29 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV63662498; called by muse, varscan2
- ADAMTS18 | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs572975589, COSV51418461; called by muse, mutect2, varscan2
- ADAMTS18 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867875220, COSV51406551; called by mutect2, varscan2
- ADARB2 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV67215072; called by muse, varscan2
- ADCY10 | c.1871T>C p.I624T | Missense Mutation (SNP) | VAF 233/369 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs780418550, COSV63242268; called by muse, mutect2, varscan2
- ADCY8 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV53914559; called by muse, mutect2, varscan2
- ADGRE1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51677676; called by muse, mutect2, varscan2
- ADGRF2 | c.1127G>A p.R376K (on ENST00000296862 / NM_001368115.2; = p.R308K on NM_153839.7) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs368691313, COSV57286389; called by muse, varscan2
- ADGRG4 | c.5580G>A p.M1860I | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54960664, COSV54963756; called by muse, mutect2, varscan2
- ADGRL2 | c.2055A>T p.K685N (on ENST00000370717 / NM_001366005.1; = p.K672N on NM_012302.4) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as COSV54675202; called by muse, mutect2, varscan2
- ADGRV1 | c.9352C>T p.Q3118* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV67989194; called by mutect2, varscan2
- ADGRV1 | c.11121G>A p.V3707= | Splice Region (SNP) | VAF 50/136 reads (37%) | catalogued as COSV67989199; called by muse, mutect2, varscan2
- ADRA1A | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs749902900, COSV52368465; called by muse, mutect2, varscan2
- AFF2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60671128; called by muse, mutect2, varscan2
- AGFG2 | c.1426A>G p.T476A | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV53545943; called by muse, mutect2, varscan2
- AHR | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV54124597; called by muse, mutect2, varscan2
- AHSP | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56528990; called by mutect2, varscan2
- AKAP1 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 98/168 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs775916699, COSV58470490; called by mutect2, varscan2
- AKT3 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV55622080; called by muse, mutect2, varscan2
- ALOX15B | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66479699; called by muse, mutect2, varscan2
- ALPK3 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs774126835, COSV51935600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPL | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66380127; called by muse, mutect2, varscan2
- AMY2A | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1372566567, COSV70214654; called by muse, mutect2, varscan2
- ANK1 | c.4810G>A p.G1604R | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV55886214; called by muse, mutect2, varscan2
- ANK3 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066579, COSV99778479; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV51851879; called by mutect2, varscan2
- ANKRD30A | c.2055G>A p.W685* (on ENST00000611781; = p.W629* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV64606298, COSV64614294; called by muse, mutect2, varscan2
- ANKRD50 | c.3809G>A p.G1270E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV72385887; called by muse, mutect2, varscan2
- ANO3 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs1461594466, COSV56797727; called by mutect2, varscan2
- ANXA9 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64485149; called by muse, mutect2, varscan2
- AOC3 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs575260524, COSV99520501; called by mutect2, varscan2
- AP002748.5 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV59149979; called by muse, mutect2, varscan2
- APBB2 | c.1627G>A p.E543K (on ENST00000295974 / NM_001166050.2; = p.E544K on NM_004307.2) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs762727771, COSV55956188; called by mutect2, varscan2
- ARHGAP35 | c.2072A>C p.N691T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV68332959; called by muse, mutect2, varscan2
- ARHGEF11 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59355863; called by muse, mutect2, varscan2
- ARMC4 | c.2398C>T p.Q800* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV59467069; called by mutect2, varscan2
- ARMCX5 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55767020; called by muse, mutect2, varscan2
- ARPP21 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51801705; called by muse, mutect2, varscan2
- ASB15 | c.935T>G p.I312S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51927246; called by muse, mutect2, varscan2
- ASXL3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.081); catalogued as COSV52466454; called by mutect2, varscan2
- ATF2 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs770984722, COSV51371057; called by muse, mutect2, varscan2
- ATG2B | c.1678T>A p.F560I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV63424133; called by muse, mutect2, varscan2
- ATP13A4 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776106725, COSV55071508; called by muse, mutect2, varscan2
- ATP1A3 | c.2505G>A p.M835I (on ENST00000545399 / NM_001256214.2; = p.M822I on NM_152296.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV57489024; called by mutect2, varscan2
- ATP2C2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.694); catalogued as COSV52298077; called by muse, mutect2, varscan2
- BANP | c.457G>T p.A153S (on ENST00000286122; = p.A122S on NM_017869.4) | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.992); catalogued as rs745483519, COSV53739592; called by muse, mutect2, varscan2
- BCCIP | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV52938468; called by mutect2, varscan2
- BCL11A | c.515C>T p.P172L (on ENST00000335712 / NM_001365609.1; = p.P206L on NM_018014.4) | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV59633142; called by muse, mutect2, varscan2
- BCL2L10 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99548660; called by muse, mutect2, varscan2
- BCO1 | c.1415-1G>A p.X472_splice | Splice Site (SNP) | VAF 33/47 reads (70%) | catalogued as COSV50730588; called by muse, mutect2, varscan2
- BCR | c.1981C>A p.L661M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs764958780, COSV100007221; called by muse, varscan2
- BEST3 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 132/162 reads (81%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV56995104; called by muse, mutect2, varscan2
- BHLHE22 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58862192, COSV99075418; called by muse, mutect2, varscan2
- BICC1 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54064821; called by muse, mutect2, varscan2
- BIRC3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV54817963, COSV54819895; called by muse, mutect2, varscan2
- BMP1 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as rs1488741825, COSV60481177; called by muse, mutect2, varscan2
- BPIFB2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401755; called by muse, mutect2, varscan2
- BPIFB2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199805090, COSV50067812; called by muse, mutect2, varscan2
- BRF2 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV55102784; called by muse, mutect2, varscan2
- BRIP1 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as COSV52002430; called by muse, mutect2, varscan2
- BRWD1 | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60898902; called by muse, varscan2
- BRWD1 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60898919; called by mutect2, varscan2
- C14orf39 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147627198, COSV58779891; called by mutect2, varscan2
- C16orf71 | c.1488G>C p.R496S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54788890; called by muse, mutect2, varscan2
- C1orf127 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs373216196; called by muse, mutect2, varscan2
- C2orf16 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV62676558; called by muse, mutect2, varscan2
- C2orf16 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs752327558, COSV100821130; called by mutect2, varscan2
- C5orf34 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV60930910; called by mutect2, varscan2
- C7 | c.2245C>T p.H749Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV57476443; called by muse, mutect2, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, mutect2, varscan2
- CACNA1E | c.5348C>T p.S1783F | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV62403545; called by muse, mutect2, varscan2
- CACNA1G | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.186); catalogued as rs1295755425, COSV61731459; called by muse, mutect2, varscan2
- CACNA2D1 | c.2183G>A p.G728E (on ENST00000356253 / NM_001366867.1; = p.G716E on NM_000722.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62383805; called by muse, mutect2, varscan2
- CAD | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53028764; called by muse, mutect2, varscan2
- CALML3 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs754327442, COSV59449136; called by muse, mutect2, varscan2
- CAMKV | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56556443; called by muse, varscan2
- CAPRIN2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.806); catalogued as COSV51833637; called by muse, mutect2, varscan2
- CAPZA3 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56855415; called by muse, mutect2, varscan2
- CASR | c.1621C>T p.L541F (on ENST00000490131; = p.L618F on NM_000388.4) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV56138410; called by muse, mutect2, varscan2
- CAVIN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV58423225; called by muse, mutect2, varscan2
- CBX2 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1434242919, COSV99491072; called by muse, mutect2, varscan2
- CCDC178 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314108944, COSV55764637; called by muse, mutect2, varscan2
- CCDC54 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV53758288; called by muse, mutect2, varscan2
- CCDC68 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs1423113467, COSV61604108; called by mutect2, varscan2
- CCDC70 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54429935; called by muse, mutect2, varscan2
- CCDC73 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58796036; called by mutect2, varscan2
- CCDC88B | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV100106081; called by muse, mutect2, varscan2
- CD180 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV56518735; called by muse, mutect2, varscan2
- CD200R1L | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1245378162, COSV68003867; called by mutect2, varscan2
- CD2AP | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs756790635, COSV100830695; called by mutect2, varscan2
- CD8B | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as COSV58926838; called by muse, mutect2, varscan2
- CDC25A | c.1223T>C p.V408A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.326); catalogued as rs1259212402, COSV56771490; called by muse, mutect2, varscan2
- CDC27 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV99296701; called by muse, mutect2, varscan2
- CDH16 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV100234321; called by muse, varscan2
- CDH16 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV55334552, COSV55337783; called by muse, mutect2, varscan2
- CDH6 | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV54073362; called by muse, mutect2, varscan2
- CDH8 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54879085; called by muse, mutect2, varscan2
- CDK5RAP1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59427712; called by muse, mutect2, varscan2
- CELF4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs769836710, COSV58458274; called by muse, mutect2, varscan2
- CELSR3 | c.9901C>T p.P3301S | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV50901360; called by muse, mutect2, varscan2
- CENPF | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV65276293; called by muse, mutect2, varscan2
- CEP350 | c.3820T>G p.S1274A | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV100855432; called by muse, mutect2, varscan2
- CEP350 | c.3821C>T p.S1274F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100855434; called by muse, mutect2, varscan2
- CEP72 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53794241; called by muse, mutect2, varscan2
- CFAP100 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs370807740; called by mutect2, varscan2
- CFAP206 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV65808264; called by muse, mutect2, varscan2
- CFAP43 | c.4833G>A p.G1611= | Splice Region (SNP) | VAF 12/71 reads (17%) | catalogued as COSV60479469; called by muse, mutect2
- CFAP43 | c.4832G>A p.G1611E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as rs762682633; called by muse, mutect2
- CFH | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV66405903, COSV66414066; called by muse, mutect2, varscan2
- CFHR2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV66381542; called by muse, varscan2
- CFHR2 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100804368, COSV100804413; called by muse, varscan2
- CFHR4 | c.1097G>A p.G366E (on ENST00000367416 / NM_001201551.2; = p.G120E on NM_006684.5) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs779607652, COSV52231524; called by muse, mutect2, varscan2
- CHI3L2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63874329; called by muse, mutect2, varscan2
- CILP | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025751; called by muse, mutect2, varscan2
- CLDN11 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV50355692; called by muse, mutect2, varscan2
- CLDN16 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs968906940, CM014949, CM034402, COSV53228456, COSV53228640; called by muse, mutect2, varscan2
- CLEC16A | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55490478; called by muse, mutect2, varscan2
- CLHC1 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs768769581, COSV68464391; called by mutect2, varscan2
- CLSTN2 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as rs1331791730, COSV101515506, COSV71722203; called by muse, mutect2, varscan2
- CMA1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs372192946; called by muse, mutect2, varscan2
- CNTNAP5 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV70494474; called by mutect2, varscan2
- CNTNAP5 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70494479; called by muse, mutect2, varscan2
- COBLL1 | c.1064C>T p.P355L (on ENST00000392717; = p.P317L on NM_014900.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52070900; called by muse, mutect2, varscan2
- COL11A1 | c.4754C>T p.S1585F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV62188540; called by muse, mutect2, varscan2
- COL13A1 | c.1963G>A p.G655R (on ENST00000398978 / NM_001130103.2; = p.G583R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240717826, COSV62571756; called by muse, mutect2, varscan2
- COL16A1 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54709415; called by muse, mutect2, varscan2
- COL21A1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55169682; called by muse, mutect2, varscan2
- COL4A4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762822768, COSV61633794; called by muse, mutect2, varscan2
- COL4A5 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV60365239; called by muse, mutect2, varscan2
- COL4A5 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60365215; called by muse, mutect2, varscan2
- COL4A6 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 88/112 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57870893; called by muse, mutect2, varscan2
- COL7A1 | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs1018322313, COSV60397842; called by muse, mutect2, varscan2
- CPB1 | c.1099T>G p.Y367D | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51574712; called by muse, mutect2, varscan2
- CPLX2 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV64001223; called by mutect2, varscan2
- CPNE2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51963392; called by muse, mutect2, varscan2
- CR1L | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.42); catalogued as COSV54328224, COSV99687834; called by muse, varscan2
- CREB3L4 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV55210539; called by muse, mutect2, varscan2
- CSDE1 | c.1600G>A p.E534K (on ENST00000358528 / NM_001007553.3; = p.E503K on NM_007158.6) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54751794; called by mutect2, varscan2
- CSMD1 | c.10438C>T p.H3480Y (on ENST00000520002; = p.H3479Y on NM_033225.6) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as COSV59344634; called by mutect2, varscan2
- CSMD1 | c.5458C>T p.P1820S (on ENST00000520002; = p.P1819S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59344645; called by muse, mutect2, varscan2
- CSMD1 | c.3866G>A p.R1289Q (on ENST00000520002; = p.R1288Q on NM_033225.6) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs780978438, COSV59300261, COSV59344665; called by muse, mutect2, varscan2
- CSMD3 | c.9740C>A p.T3247K (on ENST00000297405 / NM_001363185.1; = p.T3078K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV52161727, COSV52230716; called by muse, mutect2, varscan2
- CSMD3 | c.2225G>A p.G742E (on ENST00000297405 / NM_001363185.1; = p.G638E on NM_052900.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52230737; called by muse, mutect2, varscan2
- CUBN | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV64720056; called by muse, mutect2, varscan2
- CWF19L2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV56515373; called by muse, mutect2, varscan2
- CYP3A43 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV55936857; called by mutect2, varscan2
- DAPK3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs1188528193, COSV56663632; called by mutect2, varscan2
- DCTD | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63867039; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- DDX27 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs767675958, COSV65599129; called by mutect2, varscan2
- DEFA5 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1267769714, COSV57962283; called by muse, mutect2, varscan2
- DEFB118 | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as rs548448570, COSV53619615, COSV53620730; called by muse, mutect2, varscan2
- DEGS2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1271665031, COSV59784732; called by muse, mutect2, varscan2
- DGKB | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1458860578, COSV51786876; called by muse, mutect2, varscan2
- DGKH | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV54935468; called by mutect2, varscan2
- DHDH | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55482547; called by muse, mutect2, varscan2
- DIDO1 | c.5320C>T p.P1774S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56627147; called by muse, mutect2, varscan2
- DLGAP4 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV59419951; called by muse, mutect2, varscan2
- DLL4 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV51065617; called by muse, mutect2, varscan2
- DMD | c.6256G>A p.E2086K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs866100399, COSV63769604; called by muse, mutect2, varscan2
- DNAAF5 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445616052, COSV52419026; called by muse, mutect2, varscan2
- DNAH1 | c.12225G>A p.W4075* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV56236919; called by muse, mutect2, varscan2
- DNAH3 | c.5074A>G p.K1692E | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54532490; called by muse, mutect2, varscan2
- DNAH5 | c.10750G>A p.D3584N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210354; called by mutect2, varscan2
- DNAH5 | c.9130G>A p.E3044K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54236590; called by mutect2, varscan2
- DNAH7 | c.9265C>T p.H3089Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56772748; called by mutect2, varscan2
- DNAH7 | c.4290G>A p.M1430I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56772757; called by mutect2, varscan2
- DNAH8 | c.12932G>A p.R4311K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59460431; called by muse, mutect2, varscan2
- DPYS | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60910523, COSV60911537; called by muse, mutect2, varscan2
- DRC3 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV58264541; called by muse, varscan2
- DSC2 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV51866579; called by muse, mutect2, varscan2
- DSCAM | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68023134; called by muse, mutect2, varscan2
- DSCAM | c.3838C>T p.P1280S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68030367; called by muse, mutect2, varscan2
- DSCAM | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68021687; called by muse, mutect2, varscan2
- DSCAM | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.881); catalogued as COSV68026932; called by muse, mutect2, varscan2
- DYSF | c.1973T>G p.V658G | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50464387; called by muse, mutect2, varscan2
- DYSF | c.5104C>T p.L1702F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs11558178, COSV99251166; called by muse, mutect2, varscan2
- DYTN | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65970575; called by muse, mutect2, varscan2
- EDAR | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV51500313; called by muse, mutect2, varscan2
- EFHB | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs564514351, COSV55544858; called by mutect2, varscan2
- EFR3A | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54459252; called by muse, mutect2, varscan2
- EGF | c.1040T>A p.L347Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54480942; called by mutect2, varscan2
- EGR3 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57833967; called by muse, mutect2, varscan2
- EHD1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57735489; called by muse, varscan2
- EMC1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617529; called by muse, mutect2, varscan2
- EMC1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753052916, COSV100617530; called by muse, mutect2, varscan2
- EMP1 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 74/88 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56998941; called by muse, varscan2
- EPB41L4A | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54873980; called by muse, mutect2, varscan2
- EPHA8 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774769663, COSV51275463; called by mutect2, varscan2
- EPHB3 | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374567246; called by mutect2, varscan2
- EPN1 | c.1340C>T p.S447F (on ENST00000270460 / NM_001321263.1; = p.S421F on NM_013333.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV50039796; called by muse, varscan2
- ERC2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV55637023; called by muse, mutect2, varscan2
- ESRP2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs1390064722, COSV99251577; called by muse, mutect2, varscan2
- EVX2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1340206445, COSV57964057; called by muse, mutect2
- F2RL2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.315); catalogued as COSV56971160; called by muse, mutect2, varscan2
- F8 | c.5345T>C p.I1782T | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as CM010869, COSV64275454; called by muse, mutect2, varscan2
- FAIM | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 171/222 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58158641; called by muse, varscan2
- FAM24A | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV64406031; called by muse, mutect2, varscan2
- FAM3D | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62558684; called by mutect2, varscan2
- FAM83B | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175022, COSV60922212; called by muse, mutect2, varscan2
- FANCM | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV53532977; called by muse, mutect2
- FAT2 | c.5755C>T p.H1919Y | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV55823635; called by muse, mutect2, varscan2
- FAT2 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55823643; called by muse, mutect2, varscan2
- FBF1 | c.3338A>G p.N1113S (on ENST00000586717; = p.N1128S on NM_001319193.1) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV59865834; called by muse, mutect2, varscan2
- FBN2 | c.6878A>G p.K2293R | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1343611813, COSV52525440; called by muse, mutect2, varscan2
- FBN3 | c.6038G>C p.R2013P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767684446, COSV54462290, COSV99562064; called by muse, varscan2
- FBXO38 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57029152; called by mutect2, varscan2
- FBXO40 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57525410; called by muse, mutect2, varscan2
- FBXW7 | c.721T>C p.F241L (on ENST00000281708 / NM_001349798.2; = p.F161L on NM_018315.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV55930439; called by muse, mutect2, varscan2
- FCGR1A | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV100977307; called by muse, mutect2, varscan2
- FES | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV60999370; called by muse, mutect2, varscan2
- FGA | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.158); catalogued as COSV57395800; called by muse, mutect2, varscan2
- FGGY | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58037347; called by muse, mutect2, varscan2
- FLG | c.8258G>A p.G2753E | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV100912422; called by muse, mutect2, varscan2
- FLG | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.998); catalogued as rs1390104615, COSV64244047; called by muse, mutect2, varscan2
- FLG2 | c.6838G>A p.G2280R | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.458); catalogued as COSV66169072; called by muse, mutect2, varscan2
- FLT3 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV54045492, COSV54048726; called by muse, mutect2, varscan2
- FOXD4L5 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV101073310; called by mutect2, varscan2
- FOXN3 | c.997G>A p.E333K (on ENST00000261302; = p.E311K on NM_005197.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV54312237; called by muse, mutect2, varscan2
- FRMPD2 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as COSV59719874; called by muse, mutect2, varscan2
- FRMPD2 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV59715516; called by muse, mutect2, varscan2
- FRRS1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV54921391; called by muse, varscan2
- FST | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs371840444; called by mutect2, varscan2
- FUT10 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59659109; called by muse, mutect2, varscan2
- GALNT17 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1360134356, COSV61170936, COSV61177868; called by muse, mutect2, varscan2
- GAS7 | c.587C>T p.T196I (on ENST00000432992 / NM_201433.2; = p.T56I on NM_003644.3) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100097375; called by muse, mutect2, varscan2
- GBA3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs557215876, COSV101545591; called by muse, mutect2, varscan2
- GBE1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70100695; called by muse, mutect2, varscan2
- GDF9 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV51526710, COSV99737111; called by muse, mutect2, varscan2
- GDI2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV101201170; called by muse, mutect2, varscan2
- GHR | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.986); catalogued as COSV50118468; called by muse, mutect2, varscan2
- GIMAP4 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.532); catalogued as COSV55433451; called by muse, mutect2, varscan2
- GLCCI1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs774566628, COSV56201914; called by mutect2, varscan2
- GLRA3 | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV56864992; called by muse, mutect2, varscan2
- GOLGA1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs761834270, COSV65229002; called by mutect2, varscan2
- GOLGA6A | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99297073; called by mutect2, varscan2
- GOLGB1 | c.4351G>A p.D1451N | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs761066625, COSV61467593; called by mutect2, varscan2
- GPALPP1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62706111; called by muse, mutect2, varscan2
- GPATCH1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs150368616; called by mutect2, varscan2
- GPM6A | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs768834518, COSV54539879; called by muse, mutect2, varscan2
- GPR180 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65385801; called by muse, mutect2, varscan2
- GPR6 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV99254636; called by muse, mutect2, varscan2
- GPR85 | c.88A>T p.I30L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV51784349; called by muse, mutect2, varscan2
- GPRC5B | c.65T>A p.V22E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV56027329; called by muse, mutect2, varscan2
- GRAMD1C | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV63983196; called by muse, mutect2, varscan2
- GRIA2 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52396256; called by mutect2, varscan2
- GRID1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.894); catalogued as rs776699845, COSV60037899; called by muse, mutect2, varscan2
- GRIN2B | c.1408A>G p.K470E | Missense Mutation (SNP) | VAF 156/188 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV74206634; called by muse, mutect2, varscan2
- GRM3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64474784; called by mutect2, varscan2
- GRM4 | c.2303C>T p.T768I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV65215327; called by muse, mutect2, varscan2
- GRM6 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs145110689; called by mutect2, varscan2
- GTF3C1 | c.1193T>A p.L398Q | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62242517, COSV62245739; called by mutect2, varscan2
- GTSF1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 169/205 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59938994; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by mutect2, varscan2
- GUCY1A1 | c.1372T>A p.F458I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56653198; called by muse, mutect2, varscan2
- GUCY2C | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV53792123; called by muse, mutect2, varscan2
- HAO1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101113159, COSV66492645; called by muse, mutect2, varscan2
- HAPLN2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs941648080, COSV54816095; called by muse, mutect2, varscan2
- HCN1 | c.2610A>T p.E870D | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV57520822; called by muse, varscan2
- HCN1 | c.2552C>G p.P851R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57520832, COSV57526723; called by muse, varscan2
- HDLBP | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60495361; called by muse, mutect2, varscan2
- HELB | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 54/61 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV56074572; called by muse, mutect2, varscan2
- HELQ | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55026075; called by muse, mutect2, varscan2
- HEXA | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV51507266; called by muse, mutect2, varscan2
- HNRNPCL1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV58613127; called by muse, mutect2, varscan2
- HS3ST1 | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV50024261; called by mutect2, varscan2
- HSD17B6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 95/113 reads (84%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59108167; called by muse, mutect2, varscan2
- HSF5 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV60201604; called by muse, mutect2, varscan2
- HSPG2 | c.11788C>T p.P3930S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60828777; called by muse, mutect2, varscan2
- HUWE1 | c.1961A>C p.D654A | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53353082; called by muse, mutect2, varscan2
- HYAL4 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56139228; called by muse, mutect2, varscan2
- HYDIN | c.4406G>A p.R1469K | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.422); catalogued as COSV66832657, COSV66833195; called by muse, mutect2, varscan2
- IFT172 | c.3753C>A p.D1251E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53135711; called by muse, mutect2, varscan2
- IFT172 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV53135721; called by muse, mutect2, varscan2
- IFT88 | c.1069G>A p.D357N (on ENST00000319980 / NM_001318493.2; = p.D348N on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100179979; called by muse, mutect2, varscan2
- IGFN1 | c.1746G>A p.W582* (on ENST00000295591 / NM_001367841.1; = p.W3039* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV55176796; called by muse, mutect2, varscan2
- IGKV1D-43 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs576853442; called by muse, mutect2, varscan2
- IGSF22 | c.2659G>A p.E887K (on ENST00000319338; = p.E988K on NM_173588.4) | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.89); PolyPhen benign (0.234); catalogued as rs1260476960, COSV55011129; called by muse, mutect2, varscan2
- IGSF9 | c.1373G>A p.G458E (on ENST00000368094 / NM_001135050.2; = p.G442E on NM_020789.4) | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as COSV63640852; called by muse, varscan2
- IL12B | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV51455425, COSV51455767; called by muse, mutect2, varscan2
- IL12RB1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV59098010; called by muse, mutect2
- IL17RC | c.1058C>T p.S353F (on ENST00000295981 / NM_153461.4; = p.S267F on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV55973923; called by muse, mutect2, varscan2
- IL18RAP | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752348672, COSV51824160; called by mutect2, varscan2
- IL1A | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV54519802; called by mutect2, varscan2
- IL4 | c.136-2A>G p.X46_splice | Splice Site (SNP) | VAF 35/103 reads (34%) | catalogued as COSV51503324; called by muse, mutect2, varscan2
- ILDR1 | c.1600G>A p.E534K (on ENST00000344209 / NM_001199799.2; = p.E490K on NM_175924.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV56551251; called by muse, mutect2, varscan2
- IMMT | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV54480328, COSV54481268; called by muse, mutect2, varscan2
- INTS3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59679212; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1329A>T p.E443D (on ENST00000485419 / NM_001197113.1; = p.E367D on NM_014575.3) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100542566; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1330G>A p.A444T (on ENST00000485419 / NM_001197113.1; = p.A368T on NM_014575.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100542569; called by mutect2, varscan2
- ITGA10 | c.1149+2T>C p.X383_splice | Splice Site (SNP) | VAF 46/163 reads (28%) | catalogued as COSV65198077; called by muse, mutect2, varscan2
- ITGA3 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50319433, COSV50348205; called by muse, mutect2, varscan2
- ITGA4 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV51999064; called by mutect2, varscan2
- ITGAL | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1471278720, COSV63323057; called by muse, mutect2, varscan2
- ITPRID2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165718565, COSV57473478; called by muse, varscan2
- ITPRID2 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV57473494; called by muse, mutect2, varscan2
- JCAD | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV64760513; called by muse, mutect2, varscan2
- KALRN | c.3423+1G>A p.X1141_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as COSV53771171; called by muse, mutect2, varscan2
- KANSL1L | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762505094, COSV55993885; called by mutect2, varscan2
- KAT2B | c.557T>A p.V186D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55431376; called by mutect2, varscan2
- KAT2B | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55431391; called by muse, mutect2, varscan2
- KAT6B | c.5369C>T p.A1790V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV54750283; called by muse, varscan2
- KCNQ3 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV66474748; called by muse, varscan2
- KDM5B | c.3655C>A p.P1219T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV52509728; called by mutect2, varscan2
- KIAA1549 | c.2164T>G p.F722V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54319004; called by muse, mutect2, varscan2
- KIAA1549 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV54305054; called by muse, varscan2
- KIF13B | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73054479; called by muse, mutect2, varscan2
- KIF21B | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as rs774832342, COSV59760898; called by muse, mutect2, varscan2
- KIF26A | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59468045; called by muse, mutect2, varscan2
- KIR2DL3 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV60898762; called by muse, mutect2, varscan2
- KIR3DL2 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as COSV54389821, COSV99552418; called by muse, mutect2, varscan2
- KLF17 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs368038713; called by muse, mutect2, varscan2
- KLHDC7A | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV68770239; called by muse, mutect2, varscan2
- KLHDC8A | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336184466, COSV65678993; called by muse, mutect2, varscan2
- KLHL13 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV53244984, COSV53249868, COSV99035215; called by muse, mutect2, varscan2
- KLHL14 | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs1185749954, COSV63832299; called by mutect2, varscan2
- KLHL6 | c.912C>T p.I304= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as COSV58067643; called by mutect2, varscan2
- KMT2C | c.5744C>T p.S1915F | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV51460140; called by muse, mutect2, varscan2
- KRT37 | c.1214G>C p.R405P | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56658737; called by muse, mutect2, varscan2
- KRTAP10-10 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59968904; called by muse, mutect2, varscan2
- KRTAP15-1 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV61877657; called by muse, mutect2, varscan2
- KRTAP9-3 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); catalogued as rs1461470107, COSV66646827; called by muse, mutect2, varscan2
- LAD1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs780464600, COSV66212810; called by muse, varscan2
- LAMA1 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs750355560, COSV67539637; called by mutect2, varscan2
- LAMA1 | c.2462C>A p.P821Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.853); catalogued as rs767024233, COSV67539640; called by muse, mutect2, varscan2
- LAMP5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55716930; called by muse, varscan2
- LCT | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV51552647; called by muse, mutect2, varscan2
- LDHD | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55580313; called by mutect2, varscan2
- LGSN | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV65726379, COSV65727681; called by mutect2, varscan2
- LILRB3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV54439733; called by muse, mutect2, varscan2
- LINS1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376417416, COSV59077926; called by muse, varscan2
- LIPC | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV54424296; called by muse, mutect2, varscan2
- LIPF | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV53282651, COSV53284857; called by mutect2, varscan2
- LMAN1L | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV59002553; called by muse, mutect2
- LONRF1 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV68037246; called by muse, mutect2, varscan2
- LPGAT1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.922); catalogued as COSV65351578; called by muse, mutect2, varscan2
- LRCH4 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as COSV100053259; called by muse, mutect2, varscan2
- LRFN5 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53264337; called by mutect2, varscan2
- LRIG2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV63162890; called by muse, mutect2, varscan2
- LRRC36 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV52080496; called by muse, mutect2, varscan2
- LRRC49 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs767163230, COSV53012420; called by mutect2, varscan2
- LTBP2 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV56210360; called by muse, mutect2, varscan2
- LTBP3 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV57242032; called by muse, mutect2, varscan2
- MACF1 | c.12007C>T p.Q4003* (on ENST00000372915; = p.Q1936* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV57129791; called by muse, mutect2, varscan2
- MAGEA12 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 53/66 reads (80%) | catalogued as COSV63294883, COSV63294966; called by muse, mutect2, varscan2
- MAGEB18 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57464450; called by muse, mutect2
- MAGEC1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.485); catalogued as rs1291726010, COSV53576336; called by muse, mutect2, varscan2
- MAGEC2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV56000268; called by muse, mutect2, varscan2
- MAK | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV57566333; called by muse, varscan2
- MAP1B | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs202226597, COSV57101839; called by muse, mutect2, varscan2
- MAP3K15 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV58833508; called by muse, mutect2, varscan2
- MAP3K9 | c.2335C>T p.P779S (on ENST00000554752 / NM_001284230.1; = p.P793S on NM_033141.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV67120771; called by muse, mutect2, varscan2
- MAPK10 | c.437G>A p.G146E (on ENST00000359221 / NM_001351625.2; = p.G184E on NM_002753.5) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60386379; called by muse, mutect2, varscan2
- MATR3 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV63078162; called by muse, mutect2, varscan2
- MCM6 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51465074; called by mutect2, varscan2
- MECOM | c.1602G>A p.M534I (on ENST00000468789 / NM_001105078.4; = p.M722I on NM_004991.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52968346; called by muse, mutect2, varscan2
- METRNL | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV60761112; called by muse, mutect2, varscan2
- MFNG | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606242, COSV63690540; called by muse, mutect2, varscan2
- MGAM | c.2486C>T p.T829I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV72075013; called by muse, mutect2, varscan2
- MGAM | c.4561G>A p.G1521R | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075014; called by muse, mutect2
- MIA2 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54484549; called by mutect2, varscan2
- MIB1 | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55092180; called by muse, mutect2, varscan2
- MICALL1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1317234204, COSV99317677; called by muse, varscan2
- MKX | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs267602458, COSV65392545; called by muse, mutect2, varscan2
- MLXIPL | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57669025; called by muse, mutect2, varscan2
- MOG | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65321423; called by muse, mutect2, varscan2
- MPP2 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99290948; called by muse, varscan2
- MPP7 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61729954; called by muse, mutect2, varscan2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by mutect2, varscan2
- MROH2B | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1331319311, COSV68186140; called by muse, mutect2, varscan2
- MRTFA | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs780837181, COSV62934538; called by muse, mutect2, varscan2
- MS4A3 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 157/341 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53936864; called by muse, mutect2, varscan2
- MTMR6 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV67807848; called by muse, mutect2, varscan2
- MTMR8 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs750507967, COSV66392609; called by mutect2, varscan2
- MTOR | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63874069; called by mutect2, varscan2
- MUC13 | c.1215G>A p.K405= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as COSV60700256; called by muse, mutect2, varscan2
- MUC16 | c.20297C>T p.S6766L | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs200769888; called by mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC16 | c.7211C>A p.S2404Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67477187; called by mutect2, varscan2
- MUC16 | c.2855A>G p.N952S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.096); catalogued as COSV67477192; called by muse, mutect2, varscan2
- MUC4 | c.2713T>C p.S905P | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as COSV62164384; called by muse, mutect2, varscan2
- MXRA5 | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764545839, COSV54232960; called by mutect2, varscan2
- MYH2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV55435896; called by muse, mutect2, varscan2
- MYH4 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV55121228; called by muse, mutect2, varscan2
- MYH7B | c.2189-1G>A p.X730_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs752660275, COSV99483462; called by muse, varscan2
- MYH7B | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53422875, COSV99483464; called by muse, varscan2
- MYO1D | c.2926A>T p.K976* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57831379; called by mutect2, varscan2
- MYO3A | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56337575; called by muse, mutect2, varscan2
- MYO3A | c.4228G>A p.D1410N | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV56319253, COSV56337583; called by muse, mutect2, varscan2
- MYO9A | c.4363C>T p.L1455F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.109); catalogued as COSV61853568; called by muse, mutect2, varscan2
- MYOCD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58506770; called by muse, mutect2, varscan2
- MYOG | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV54096037, COSV99613979; called by muse, mutect2, varscan2
- MYOM3 | c.4244C>T p.S1415F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58396440; called by muse, mutect2, varscan2
- NBR1 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57833675; called by muse, mutect2, varscan2
- NCSTN | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54189005; called by muse, mutect2, varscan2
- NDST3 | c.1331T>A p.I444N | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56622712; called by muse, mutect2, varscan2
- NDST3 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV56622729; called by muse, mutect2, varscan2
- NEB | c.10789A>G p.K3597E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV51431015; called by muse, mutect2, varscan2
- NEK9 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.506); catalogued as COSV53132025; called by muse, varscan2
- NEU1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 146/530 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV57668011; called by mutect2, varscan2
- NEURL4 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV59760605; called by muse, mutect2, varscan2
- NEUROG2 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.034); catalogued as COSV57637704; called by muse, mutect2, varscan2
- NF1 | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as CS000866, CS1311497, COSV100647696, COSV62195996, COSV62209211; called by muse, mutect2, varscan2
- NF1 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CD086495, COSV62209215; called by muse, mutect2, varscan2
- NGEF | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs763007458, COSV50916295; called by mutect2, varscan2
- NIPBL | c.4950A>T p.Q1650H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.706); catalogued as COSV56956195, COSV56956910; called by muse, mutect2, varscan2
- NLRC5 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52658368; called by muse, mutect2, varscan2
- NLRC5 | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs759791431, COSV52658373; called by mutect2, varscan2
- NLRC5 | c.3775G>A p.G1259R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs144677515; called by muse, mutect2, varscan2
- NOL6 | c.1146G>A p.L382= | Splice Region (SNP) | VAF 86/102 reads (84%) | catalogued as COSV53043320; called by muse, mutect2, varscan2
- NOTCH4 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 131/409 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV66681957; called by muse, mutect2, varscan2
- NPAP1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs267604136, COSV61508591; called by mutect2, varscan2
- NPBWR2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs769015617, COSV63900320; called by muse, mutect2, varscan2
- NPC1L1 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56923357; called by muse, mutect2, varscan2
- NR5A2 | c.1315C>T p.R439C (on ENST00000367362 / NM_205860.3; = p.R393C on NM_003822.5) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs762506535, COSV52645342; called by mutect2, varscan2
- NRXN1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV58466870; called by muse, mutect2, varscan2
- NRXN3 | c.2591G>A p.G864E (on ENST00000335750 / NM_001330195.2; = p.G491E on NM_004796.6) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745506360, COSV59738874; called by muse, mutect2, varscan2
- NSUN4 | c.1051A>T p.T351S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV61063448; called by muse, varscan2
- NUFIP1 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63151569; called by muse, mutect2, varscan2
- NUTM1 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV59217627; called by muse, mutect2, varscan2
- NXF3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV67704279; called by muse, varscan2
- NXN | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61097876; called by mutect2, varscan2
- NYNRIN | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as rs1472146683, COSV66843393; called by muse, mutect2, varscan2
- OR10G4 | c.599T>G p.V200G | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV57978261; called by muse, varscan2
- OR14J1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs756075788, COSV65845752; called by muse, mutect2, varscan2
- OR1B1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs757251330, COSV59171979; called by muse, mutect2, varscan2
- OR2A5 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68738894; called by muse, mutect2, varscan2
- OR2F1 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV67331651; called by muse, mutect2, varscan2
- OR2G3 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60680733; called by muse, mutect2, varscan2
- OR2L2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 131/207 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142994715, COSV63549338; called by muse, mutect2, varscan2
- OR2M5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV63545727; called by muse, varscan2
- OR2T1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs756402494, COSV63541543; called by mutect2, varscan2
- OR2W3 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs761957438, COSV64457399; called by muse, mutect2, varscan2
- OR4A5 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as rs749865354, COSV100157365; called by muse, mutect2, varscan2
- OR4B1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58883281; called by muse, mutect2, varscan2
- OR4K2 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100064156, COSV53850349; called by muse, mutect2, varscan2
- OR4K2 | c.259A>C p.T87P | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100064191, COSV53850359; called by muse, mutect2, varscan2
- OR4N2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV60052743, COSV60053213; called by muse, mutect2, varscan2
- OR52D1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs746533430, COSV59487372; called by muse, mutect2, varscan2
- OR52R1 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372915441; called by muse, mutect2, varscan2
- OR5AC2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62279767; called by muse, mutect2, varscan2
- OR5T1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV57303558; called by muse, mutect2, varscan2
- OR6K6 | c.778G>A p.G260S (on ENST00000368144; = p.G236S on NM_001005184.1) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as rs1026320378, COSV63744415; called by muse, mutect2, varscan2
- OR7G1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.308); catalogued as COSV53318075; called by muse, mutect2, varscan2
- OR7G2 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs764574376, COSV59688371, COSV59688637; called by muse, mutect2, varscan2
- OR8H3 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV57909853; called by mutect2, varscan2
- OR8U1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164153, COSV56414361; called by muse, mutect2, varscan2
- P3H1 | c.1939A>T p.R647* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as COSV52535008; called by mutect2, varscan2
- P3H3 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51834592; called by muse, mutect2, varscan2
- P4HA1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV54962949; called by muse, mutect2, varscan2
- P4HA2 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs764954173, COSV51323847; called by muse, mutect2, varscan2
- PALMD | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.701); catalogued as rs1203535852, COSV54165396; called by muse, mutect2, varscan2
- PAPPA2 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.586); catalogued as rs745653226, COSV62773968; called by muse, mutect2, varscan2
- PARP4 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1263975946, COSV67961383; called by mutect2, varscan2
- PARP8 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV55862442; called by muse, mutect2, varscan2
- PAX8 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1190937197, COSV54510317; called by muse, mutect2, varscan2
- PCDH12 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV51522474; called by muse, mutect2, varscan2
- PCDHA10 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56520323; called by mutect2, varscan2
- PCDHA5 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV65353988; called by muse, mutect2, varscan2
- PCDHA9 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV65328651; called by muse, mutect2, varscan2
- PCDHB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); catalogued as COSV50585921; called by muse, mutect2, varscan2
- PCDHB5 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as rs1554275938, COSV50652336; called by mutect2, varscan2
- PCDHGA1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV65296862; called by muse, mutect2, varscan2
- PCDHGB5 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53979006; called by muse, mutect2, varscan2
- PCDHGC3 | c.1952A>G p.N651S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs560968418, COSV52757536; called by muse, mutect2, varscan2
- PCDHGC4 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.938); catalogued as COSV52757547; called by mutect2, varscan2
- PCED1B | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 85/100 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71395408; called by muse, mutect2, varscan2
- PCLO | c.14920C>T p.P4974S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61621946; called by muse, mutect2, varscan2
- PCSK6 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs748780414, COSV59342452; called by mutect2, varscan2
- PDE1A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs145482728, COSV59527650; called by muse, mutect2, varscan2
- PDE6B | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55327946; called by muse, mutect2, varscan2
- PDE6C | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65116525; called by muse, mutect2, varscan2
- PDE8B | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV53740322; called by muse, mutect2, varscan2
- PDZD2 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56863501; called by muse, mutect2, varscan2
- PELP1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52589478; called by mutect2, varscan2
- PES1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs145353108; called by muse, mutect2, varscan2
- PEX19 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV63619799; called by muse, mutect2, varscan2
- PHLDB2 | c.3739G>T p.G1247C (on ENST00000393925 / NM_001134439.2; = p.G1204C on NM_145753.2) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56325560; called by mutect2, varscan2
- PHLPP1 | c.3239T>G p.M1080R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV53032252; called by muse, mutect2, varscan2
- PHYH | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs947056017, COSV53814877; called by muse, mutect2, varscan2
- PIGO | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs775992273, COSV53054254; called by mutect2, varscan2
- PIK3C2G | c.2701G>A p.E901K (on ENST00000676171; = p.E860K on NM_004570.5) | Missense Mutation (SNP) | VAF 70/80 reads (88%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV56816951, COSV56831913; called by muse, mutect2, varscan2
- PIP | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52120930; called by muse, varscan2
- PIWIL4 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs550779043, COSV54410484; called by muse, mutect2, varscan2
- PKD1L1 | c.7514C>T p.S2505F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV51843413; called by mutect2, varscan2
- PKD1L1 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV56970271; called by muse, mutect2, varscan2
- PKP3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs763137982, COSV58988233; called by muse, mutect2
- PLA2R1 | c.1556G>A p.W519* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV51781778; called by muse, varscan2
- PLAG1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100388320; called by muse, mutect2, varscan2
- PLAG1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); catalogued as COSV100388323; called by muse, mutect2, varscan2
- PLB1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59829541; called by muse, mutect2, varscan2
- PLCH1 | c.3455C>T p.S1152F (on ENST00000340059 / NM_001130960.2; = p.S1144F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV58194305; called by muse, mutect2, varscan2
- PLCXD3 | c.813-1G>A p.X271_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100126615; called by muse, mutect2, varscan2
- PLEKHA8 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573269600, COSV51652464; called by muse, mutect2, varscan2
- PLXNA1 | c.864C>G p.D288E | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV52528924; called by muse, mutect2, varscan2
- POLE | c.4144C>T p.R1382C | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs5744904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53560297; called by muse, mutect2, varscan2
- PPARGC1B | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV100495317; called by muse, mutect2, varscan2
- PPARGC1B | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100495319; called by mutect2, varscan2
- PPFIA4 | c.2696C>T p.S899F (on ENST00000447715; = p.S900F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55317727; called by muse, mutect2, varscan2
- PPIP5K2 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100384369; called by mutect2, varscan2
- PPIP5K2 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276783468, COSV100384371; called by muse, mutect2, varscan2
- PRB4 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 98/170 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV54396145; called by muse, varscan2
- PRDM14 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52573421; called by mutect2, varscan2
- PREX2 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV55764222, COSV55781777; called by muse, mutect2, varscan2
- PREX2 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.017); catalogued as rs1017780787, COSV55781800, COSV99905516; called by muse, mutect2, varscan2
- PRKDC | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193694024, COSV58057023; called by muse, mutect2, varscan2
- PRMT8 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54216024; called by mutect2, varscan2
- PRPF8 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59264919; called by muse, mutect2, varscan2
- PRUNE1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54846395, COSV54847763; called by muse, mutect2, varscan2
- PRUNE2 | c.2350A>T p.N784Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100945354, COSV65043509; called by mutect2, varscan2
- PSD | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV50048763; called by muse, mutect2, varscan2
- PSG1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54952666; called by muse, mutect2, varscan2
- PSG4 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs138668740, COSV54937886; called by mutect2, varscan2
- PSG4 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.257); catalogued as COSV54937352; called by muse, mutect2, varscan2
- PTPDC1 | c.1823A>G p.E608G (on ENST00000375360 / NM_177995.3; = p.E660G on NM_152422.4) | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV56624379; called by muse, mutect2, varscan2
- PTPN5 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV62127032; called by muse, mutect2, varscan2
- PTPRS | c.4909C>T p.Q1637* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | catalogued as COSV53626010; called by muse, varscan2
- PTPRS | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53626032; called by muse, mutect2, varscan2
- PTX4 | c.484C>T p.H162Y (on ENST00000447419 / NM_001328608.2; = p.H157Y on NM_001013658.1) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.25); catalogued as COSV53514270; called by muse, mutect2, varscan2
- RAB27B | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs753780291, COSV50494748; called by mutect2, varscan2
- RANBP2 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51703599; called by muse, mutect2, varscan2
- RARS1 | c.122T>A p.L41* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV51564577; called by muse, varscan2
- RBM12 | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV58292890; called by muse, varscan2
- RBM46 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.159); catalogued as COSV55977041; called by muse, mutect2, varscan2
- RECQL5 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV58637576; called by mutect2, varscan2
- REG1A | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52070293; called by muse, mutect2, varscan2
- RELL2 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV51836955; called by mutect2, varscan2
- RFX6 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.335); catalogued as COSV60586740; called by mutect2, varscan2
- RGL1 | c.1709C>T p.S570F (on ENST00000360851 / NM_001297672.2; = p.S605F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1140534, COSV58988858; called by muse, mutect2, varscan2
- RNF10 | c.1254G>A p.K418= | Splice Region (SNP) | VAF 57/67 reads (85%) | catalogued as rs747364566, COSV58046484; called by muse, mutect2, varscan2
- RNF17 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.101); catalogued as COSV55044250; called by mutect2, varscan2
- RNF180 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV56963154; called by muse, mutect2, varscan2
- RNF213 | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV60626291; called by muse, mutect2, varscan2
- RP1 | c.4582A>T p.I1528F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1209471045, CD1412817, COSV55120438; called by muse, mutect2, varscan2
- RP1 | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs767428962, COSV55120455; called by muse, mutect2, varscan2
- RP1L1 | c.5654C>T p.P1885L | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV66757163; called by muse, mutect2, varscan2
- RP1L1 | c.5014C>T p.P1672S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs750551276, COSV66761187; called by muse, mutect2, varscan2
- RPGRIP1L | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 208/606 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1406955571, COSV100047053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPGRIP1L | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 210/612 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV100047055; called by muse, mutect2, varscan2
- RPL4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs138828871, COSV57178577; called by mutect2, varscan2
- RPS6KA5 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV56223271; called by muse, mutect2, varscan2
- RYR2 | c.4804C>T p.Q1602* | Nonsense Mutation (SNP) | VAF 17/24 reads (71%) | catalogued as COSV63694627, COSV63695640; called by muse, mutect2, varscan2
- SAFB2 | c.2360C>T p.S787L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs777512759, COSV53043477; called by mutect2, varscan2
- SALL3 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs2974290, COSV73306202; called by mutect2, varscan2
- SCAMP1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs1430274486, COSV57241148; called by muse, mutect2, varscan2
- SCD5 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60296941; called by muse, mutect2, varscan2
- SCN10A | c.4979C>T p.S1660L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998456008, COSV71861374; called by muse, mutect2, varscan2
- SCN5A | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473567, CM100651, COSV61130476; ClinVar: not provided; called by muse, mutect2, varscan2
- SCTR | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV50029299; called by muse, varscan2
- SEMA3G | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV51596698; called by muse, mutect2, varscan2
- SEMA4C | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs769665682, COSV59691428; called by muse, mutect2, varscan2
- SEMG1 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54873592; called by muse, mutect2, varscan2
- SEMG2 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.187); catalogued as rs375466559; called by muse, mutect2, varscan2
- SERINC5 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs768554900, COSV72596516; called by mutect2, varscan2
- SERPINB11 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV66957298; called by muse, mutect2, varscan2
- SERPINC1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62929755; called by muse, mutect2, varscan2
- SF3B1 | c.2692T>C p.Y898H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV59206566; called by muse, mutect2, varscan2
- SFTPD | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64853389; called by muse, mutect2, varscan2
- SGIP1 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52768973, COSV52769295; called by muse, varscan2
- SHISA3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59980187; called by muse, varscan2
- SI | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV52286722; called by muse, mutect2, varscan2
- SIRPB1 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV53539504; called by muse, mutect2, varscan2
- SIRT5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 148/532 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs774041199, COSV63081164; called by mutect2, varscan2
- SLC10A3 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54836708, COSV99682278; called by muse, mutect2, varscan2
- SLC18A1 | c.880T>A p.F294I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV99369020; called by mutect2, varscan2
- SLC25A18 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376317627; called by muse, mutect2, varscan2
- SLC25A23 | c.674T>G p.I225S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV51193022, COSV99902549; called by muse, mutect2, varscan2
- SLC27A6 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs370892487, COSV52484783; called by muse, mutect2, varscan2
- SLC28A2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61664569; called by muse, mutect2, varscan2
- SLC4A1 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV52261366; called by muse, varscan2
- SLC6A12 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV62885574; called by muse, mutect2, varscan2
- SLC9A9 | c.286A>T p.N96Y | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57234239; called by mutect2, varscan2
- SLCO1C1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 134/165 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56875234; called by muse, mutect2, varscan2
- SLCO3A1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100575958; called by muse, mutect2, varscan2
- SLIT2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1270459209, COSV56580240; called by muse, mutect2, varscan2
- SLIT3 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60618532; called by muse, mutect2, varscan2
- SLITRK3 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV53846067; called by muse, mutect2, varscan2
- SLK | c.69C>A p.H23Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59826733; called by muse, mutect2, varscan2
- SMARCAL1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as rs772642936, COSV61921915; called by muse, mutect2, varscan2
- SMO | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs138284001; called by muse, mutect2, varscan2
- SMPD4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs755218803, COSV60079083, COSV60081308; called by mutect2, varscan2
- SMPD4 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100302888; called by muse, mutect2, varscan2
- SMYD1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV70225456; called by muse, mutect2, varscan2
- SNCAIP | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV54414693; called by muse, mutect2, varscan2
- SNX11 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63658824; called by muse, mutect2, varscan2
- SOX10 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62806915; called by muse, mutect2
- SP110 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs199753725, COSV51256631; called by muse, varscan2
- SP6 | c.831G>C p.W277C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60618408; called by muse, mutect2, varscan2
- SP7 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 20/25 reads (80%) | catalogued as COSV58191224; called by muse, mutect2, varscan2
- SPACA1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52760555; called by mutect2, varscan2
- SPAG1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52560296, COSV52561047; called by mutect2, varscan2
- SPATA25 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51943147; called by muse, varscan2
- SPDYC | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV101017359; called by mutect2, varscan2
- SPEG | c.9484T>A p.Y3162N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.602); catalogued as COSV56673410; called by mutect2, varscan2
- SPHKAP | c.4519C>T p.P1507S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs1353291245, COSV60884757; called by muse, varscan2
- SPINK5 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV56257517; called by muse, varscan2
- SPINT2 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56648288; called by muse, mutect2, varscan2
- SPP2 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51445939; called by muse, mutect2, varscan2
- SPTA1 | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV63756019; called by muse, mutect2, varscan2
- SPTA1 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as COSV63750498; called by muse, mutect2, varscan2
- SREBF1 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV55417808; called by muse, mutect2, varscan2
- SRGAP3 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100841522; called by muse, mutect2, varscan2
- SSH3 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100354938; called by muse, mutect2, varscan2
- SSTR1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57456678; called by muse, mutect2, varscan2
- ST3GAL6 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as rs761826510, COSV54583224; called by mutect2, varscan2
- STARD13 | c.1232C>T p.S411F (on ENST00000336934 / NM_001243476.3; = p.S293F on NM_052851.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55232979; called by muse, mutect2, varscan2
- STAU2 | c.1373C>T p.S458L (on ENST00000524300 / NM_001164380.2; = p.S426L on NM_014393.2) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1470177363, COSV63306991; called by mutect2, varscan2
- STON1-GTF2A1L | c.3025G>A p.G1009R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV100562372; called by muse, mutect2, varscan2
- STOX1 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV53815992; called by muse, mutect2, varscan2
- STXBP5L | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs540280160, COSV56521057, COSV56525874; called by muse, mutect2, varscan2
- SULT1B1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60208278; called by muse, varscan2
- SUPT6H | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58928862; called by muse, mutect2, varscan2
- SVEP1 | c.6541G>A p.E2181K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs765298196, COSV52840958; called by muse, mutect2, varscan2
- SYCP1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65699013; called by mutect2, varscan2
- SYT16 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV70857694; called by muse, mutect2, varscan2
- SYT3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV58895786; called by muse, varscan2
- SYTL1 | c.1484C>T p.S495F (on ENST00000543823; = p.S483F on NM_032872.3) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100539670; called by muse, mutect2, varscan2
- TACC2 | c.7130C>T p.S2377F (on ENST00000334433; = p.S455F on NM_006997.4) | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs955858634, COSV53284090; called by muse, mutect2, varscan2
- TAOK1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594502, COSV99914272; called by muse, mutect2, varscan2
- TARBP1 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 131/212 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV50190763; called by muse, mutect2, varscan2
- TBC1D2 | c.2653C>T p.H885Y (on ENST00000465784 / NM_001267571.2; = p.H874Y on NM_018421.4) | Missense Mutation (SNP) | VAF 85/124 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs1274868311, COSV59786271; called by muse, mutect2, varscan2
- TBX4 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53608284; called by muse, mutect2, varscan2
- TBXA2R | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200877346, COSV64344042; called by muse, mutect2, varscan2
- TBXAS1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54948598; called by muse, mutect2, varscan2
- TC2N | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.1); catalogued as COSV61747510; called by muse, mutect2, varscan2
- TCERG1 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV57038894; called by muse, mutect2, varscan2
- TDRD5 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54245847; called by mutect2, varscan2
- TENM2 | c.3187C>T p.P1063S (on ENST00000518659 / NM_001122679.2; = p.P831S on NM_001080428.3) | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.607); catalogued as COSV69134828; called by muse, mutect2, varscan2
- TENM2 | c.6548G>A p.G2183D (on ENST00000518659 / NM_001122679.2; = p.G1944D on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69134841; called by muse, mutect2, varscan2
- TEP1 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV52995323; called by muse, mutect2, varscan2
- TFAP2B | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV53829107; called by muse, mutect2, varscan2
- TFPT | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV57837858; called by muse, mutect2, varscan2
- TGIF2LX | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV99383581; called by muse, mutect2, varscan2
- TGM7 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.82); PolyPhen probably damaging (1); catalogued as rs377667253; called by muse, mutect2, varscan2
- THBS1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.096); catalogued as rs1236362449, COSV52953588, COSV52955289; called by muse, mutect2, varscan2
- THSD4 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55975145; called by muse, mutect2, varscan2
- TLL1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50263164; called by mutect2, varscan2
- TLN2 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780364585, COSV60891734, COSV60893860; called by muse, varscan2
- TLR8 | c.2654C>T p.S885F (on ENST00000218032 / NM_138636.5; = p.S903F on NM_016610.4) | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54318827; called by muse, mutect2, varscan2
- TMEM101 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV52813529; called by muse, varscan2
- TMEM132D | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 104/120 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1481575226, COSV67161000; called by muse, mutect2, varscan2
- TMEM156 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs747086721, COSV60744838; called by muse, mutect2, varscan2
- TMEM184A | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs769573814, COSV52471891; called by mutect2, varscan2
- TMEM63B | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1193223972, COSV52480494; called by muse, mutect2, varscan2
- TMEM63C | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV53605277; called by muse, mutect2, varscan2
- TMIGD3 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs1461518512, COSV62728244; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TNFRSF10D | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs557200270, COSV57036585; called by muse, mutect2, varscan2
- TNFSF11 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53478352; called by mutect2, varscan2
- TNKS2 | c.795+2T>C p.X265_splice | Splice Site (SNP) | VAF 57/132 reads (43%) | catalogued as COSV65416017; called by muse, mutect2, varscan2
- TNN | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV53429565; called by muse, mutect2, varscan2
- TNPO3 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11538883, COSV55283794; called by muse, varscan2
- TOGARAM2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369968827; called by mutect2, varscan2
- TP63 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV53201888; called by muse, mutect2, varscan2
- TPO | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61093940; called by mutect2, varscan2
- TRAT1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55467290; called by mutect2, varscan2
- TRIB1 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 120/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61335057; called by muse, varscan2
- TRIM55 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.629); catalogued as COSV52542272; called by muse, mutect2, varscan2
- TRNT1 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as rs965646183, COSV52408820; called by muse, mutect2, varscan2
- TRPC5 | c.2233-1G>A p.X745_splice | Splice Site (SNP) | VAF 42/50 reads (84%) | catalogued as COSV99463301; called by muse, mutect2, varscan2
- TRPC7 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV61457468, COSV61460049; called by muse, mutect2, varscan2
- TRPC7 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV61460059; called by muse, mutect2, varscan2
- TTC3 | c.1659+2T>C p.X553_splice | Splice Site (SNP) | VAF 28/72 reads (39%) | catalogued as COSV61292782; called by muse, mutect2, varscan2
- TTN | c.77542A>G p.T25848A (on ENST00000591111; = p.T18424A on NM_003319.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | PolyPhen benign (0.164); catalogued as COSV59891176; called by muse, mutect2, varscan2
- TTN | c.33022G>A p.V11008M (on ENST00000591111; = p.V10081M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | PolyPhen benign (0.001); catalogued as COSV60111975, COSV60168867; called by muse, mutect2, varscan2
- TTN | c.30626T>C p.V10209A (on ENST00000591111; = p.V9282A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | PolyPhen benign (0); catalogued as COSV60168876; called by mutect2, varscan2
- TTN | c.19282C>T p.P6428S (on ENST00000591111; = p.P5501S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | PolyPhen benign (0.311); catalogued as rs756864644, COSV60168893, COSV60285342; called by muse, mutect2, varscan2
- TYRO3 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55484662; called by mutect2, varscan2
- UBASH3A | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs149115903, COSV52310276; called by mutect2, varscan2
- UBXN8 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs751097233, COSV55665073; called by muse, mutect2, varscan2
- UGT2B17 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58502039; called by muse, mutect2, varscan2
- UNC13C | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs866841718, COSV52893409; called by mutect2, varscan2
- UNC5B | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1487565068, COSV58978455; called by muse, mutect2, varscan2
- USH2A | c.13601G>A p.G4534E | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56393689; called by muse, mutect2, varscan2
- USP19 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.641); catalogued as rs199888889; called by muse, mutect2, varscan2
- USP8 | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV56165700; called by muse, mutect2, varscan2
- VCAN | c.2810T>A p.V937E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); catalogued as rs1487251546, COSV54109201; called by muse, mutect2, varscan2
- VCAN | c.3467C>T p.P1156L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54109217; called by muse, mutect2, varscan2
- VN1R4 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV60805264; called by muse, varscan2
- VRK2 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs1171709314, COSV60878362; called by muse, varscan2
- VWA2 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53908048; called by muse, mutect2, varscan2
- VWA7 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 150/263 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV65173697; called by muse, mutect2, varscan2
- WBP2NL | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV60920000; called by muse, mutect2, varscan2
- WDR17 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV54570656; called by muse, mutect2, varscan2
- WNT4 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51604468; called by muse, varscan2
- WNT9B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs568737032, COSV51519168; called by muse, mutect2, varscan2
- YY1AP1 | c.1105G>A p.E369K (on ENST00000295566 / NM_139118.2; = p.E312K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99803734, COSV99804874; called by muse, mutect2, varscan2
- ZFAT | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV64735347; called by muse, mutect2, varscan2
- ZFHX3 | c.6784G>A p.D2262N | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs953863150, COSV51711266; called by mutect2, varscan2
- ZFPM2 | c.1666A>G p.T556A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374672861; called by muse, mutect2, varscan2
- ZMYND15 | c.1145-1G>A p.X382_splice | Splice Site (SNP) | VAF 61/145 reads (42%) | catalogued as COSV52643093; called by muse, mutect2, varscan2
- ZNF135 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs200161186, COSV57883575; called by muse, mutect2, varscan2
- ZNF202 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1425303234, COSV60247618; called by muse, mutect2, varscan2
- ZNF28 | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV60424037; called by muse, varscan2
- ZNF320 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67088434; called by mutect2, varscan2
- ZNF331 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53477929; called by muse, mutect2, varscan2
- ZNF345 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100080485; called by muse, mutect2, varscan2
- ZNF345 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs1250860316, COSV100080487; called by muse, mutect2, varscan2
- ZNF385D | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55763082; called by muse, mutect2, varscan2
- ZNF486 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV58720373; called by muse, mutect2, varscan2
- ZNF554 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57886207; called by muse, mutect2, varscan2
- ZNF563 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1422145690, COSV53371112; called by muse, mutect2, varscan2
- ZNF585B | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57216112; called by mutect2, varscan2
- ZNF611 | c.1979T>A p.V660E | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV60541749; called by muse, mutect2, varscan2
- ZNF611 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs750313321, COSV60541758; called by muse, mutect2, varscan2
- ZNF627 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63142469; called by muse, varscan2
- ZNF646 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 66/175 reads (38%) | catalogued as COSV54925324; called by muse, mutect2, varscan2
- ZNF667 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52635772, COSV52636395; called by muse, mutect2, varscan2
- ZNF699 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58026155; called by muse, varscan2
- ZNF773 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56589216; called by muse, mutect2, varscan2
- ZNF782 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56653724; called by muse, mutect2, varscan2
- ZNF83 | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56530885; called by muse, mutect2, varscan2
- ZNF831 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64042117; called by muse, mutect2, varscan2
- ZNF831 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs543089092, COSV64042121; called by muse, mutect2, varscan2
- ZP2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV54814966; called by muse, varscan2
- ZPLD1 | c.314G>A p.G105E (on ENST00000466937 / NM_001329788.1; = p.G121E on NM_175056.2) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV60352347; called by muse, mutect2, varscan2
- ZSCAN21 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52851350; called by muse, varscan2
- ZSWIM3 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as COSV54849064; called by muse, mutect2, varscan2
- ACACA | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- AFP | c.943_951del p.I315_A317del | In Frame Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- DDX52 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- DNAH7 | c.3837del p.E1280Kfs*4 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- GPR179 | c.4447G>A p.E1483K (on ENST00000621958; = p.E1482K on NM_001004334.4) | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, varscan2
- GRIK3 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGBP1P2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 108/174 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGHV4-28 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KDM3B | c.2761_2762del p.R921Vfs*5 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- LRRC4C | c.197dup p.N66Kfs*4 | Frame Shift Ins (INS) | VAF 27/39 reads (69%) | called by mutect2, pindel, varscan2
- MROH1 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SNRK | c.2114_2124del p.K705Rfs*9 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | called by pindel, varscan2
- SNX13 | c.2861del p.L954Cfs*19 | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel
- SPANXB1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMEM236 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV12-3 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
398 further variants in this file (3 protein-altering or splice-affecting, 362 silent, 33 other) are not listed here.
